Gene-level copy-number profile of tumor specimen TARGET-40-PARJXU-01A from TARGET case TARGET-40-PARJXU, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 12.7 years (4,624 days).
Specimen TARGET-40-PARJXU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.1cdd3125-843c-5951-940b-aca971ba08ed.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PARJXU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 411 have no estimate.
https://portal.gdc.cancer.gov/files/78c0d041-78d1-4efc-b536-811dee93fe5c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 540; copy number 1: 1,530; copy number 2: 13,278; copy number 3: 20,894; copy number 4: 14,351; copy number 5: 6,794; copy number 6: 1,174; copy number 7: 221; copy number 8: 167; copy number 9: 950; copy number 10: 247; copy number 11: 39; copy number 12: 1; copy number 14: 26.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,709,235–117,027,039, 7 genes: TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr5:165,609,441–165,905,608, 3 genes: RN7SKP60, AC008562.1, AC008489.1.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr12:9,480,608–9,576,275, 2 genes: AC092821.1, AC092821.2.
- chr17:6,207,163–6,207,269, 1 gene: RNU6-1264P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,518 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–178,484,147, 1,153 genes, copy number 7–14 (within-gene range 3–14) (broad region; genes not listed).
- chr1:181,962,889–185,657,168, 88 genes, copy number 9 (broad region; genes not listed).
- chr1:186,375,838–188,156,180, 19 genes, copy number 8–10: ODR4, PDC-AS1, PDC, AL096803.3, AL096803.1, AL096803.2, AL049198.1, PTGS2, PACERR, PLA2G4A, LINC01036, AL391813.1, FDPSP1, AL357559.1, SLC4A1APP2, AL645474.1, AL136372.2, AL136372.1, RN7SKP156.
- chr2:88,811,186–88,861,563, 2 genes, copy number 8 (within-gene range 5–8): MALLP2, AC244205.1.
- chr2:88,857,161–91,714,745, 101 genes, copy number 8 (broad region; genes not listed).
- chr3:85,799,987–87,052,738, 11 genes, copy number 7: CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1.
- chr6:67,210,408–67,467,308, 3 genes, copy number 9: AL591004.1, AL365503.1, RNA5SP208.
- chr6:71,886,703–72,403,143, 2 genes, copy number 10: RIMS1, AL035633.1.
- chr9:27,829,276–27,944,497, 2 genes, copy number 7: AL360014.1, AL353746.1.
- chr9:29,214,322–29,826,711, 5 genes, copy number 7–9: AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1.
- chr9:30,935,485–30,990,572, 2 genes, copy number 8: FTLP4, HSPA8P17.
- chr9:32,886,601–33,025,130, 1 gene, copy number 7 (within-gene range 5–7): APTX.
- chr9:32,945,996–33,182,865, 8 genes, copy number 7: ASS1P12, TCEA1P4, LAGE3P1, DNAJA1, SMU1, B4GALT1, B4GALT1-AS1, RNU4ATAC15P.
- chr9:34,109,171–34,590,140, 22 genes, copy number 8: TUBB4BP2, AL354989.2, UBAP1, RPL35AP2, AL353662.2, RNA5SP282, AL353662.1, KIF24, RNU2-50P, SERPINH1P1, NUDT2, MYORG, C9orf24, Y_RNA, FAM219A, DNAI1, RN7SKP24, ENHO, AL160270.1, AL160270.2, CNTFR, CNTFR-AS1.
- chr9:37,383,178–37,592,604, 11 genes, copy number 8: LINC01627, GRHPR, CHCHD4P3, ZBTB5, KCTD9P3, POLR1E, AL158156.1, AL513165.1, FBXO10, AL513165.2, TOMM5.
- chr9:37,636,688–37,832,117, 5 genes, copy number 8 (within-gene range 4–8): RAB1C, FRMPD1, RN7SKP171, TRMT10B, EXOSC3.
- chr13:23,134,174–23,502,874, 12 genes, copy number 9: HMGA1P6, RNY3P4, LINC00362, SGCG, RNU6-58P, TATDN2P3, SDAD1P4, SACS, RPLP1P13, SACS-AS1, LINC00327, LINC00352.
- chr13:25,371,974–26,025,851, 1 gene, copy number 7 (within-gene range 2–7): ATP8A2.
- chr13:25,863,250–26,688,948, 17 genes, copy number 7 (within-gene range 2–7): AL157366.1, RN7SL741P, RNY1P3, SHISA2, LINC00415, ATP8A2P3, PRUNEP1, RNF6, AL138966.2, AL138966.1, THAP12P6, CDK8, AL159159.1, AL353789.1, WASF3, RPS3AP44, WASF3-AS1.
- chr16:69,703,065–69,975,344, 11 genes, copy number 7: AC012321.1, NQO1, AC092115.2, AC092115.3, NOB1, AC092115.1, WWP2, SNORA62, MIR140, CLEC18A, AC026468.1.
- chr16:69,976,388–69,996,188, 1 gene, copy number 7: NPIPB14P.
- chr21:14,371,115–14,383,484, 1 gene, copy number 10: HSPA13.
- chr21:15,614,283–16,645,467, 17 genes, copy number 8–10 (within-gene range 5–10): RNU6-1326P, RAD23BP3, USP25, RBPMSLP, MIR99AHG, RNU6-426P, VDAC2P1, RPS26P5, SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2.
- chr21:17,210,469–18,486,599, 23 genes, copy number 8–11: NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1, AP000432.2, C21orf91-OT1, C21orf91, AL109761.1, CHODL-AS1, RPL37P3, CHODL, AF130417.1, TMPRSS15, AL109763.1.

Autosomal genes at a single copy (total copy number 1): 692. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
